Somatic mutation profile of tumor specimen BA2724D (aliquot aq-BA2724D) from BEATAML1.0 case 2041, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.1 years (24,497 days).
Specimen BA2724D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acaed311-2c42-4791-aa83-843cf6f01be0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2654D (Solid Tissue Normal), aliquot aq-BA2654D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4b2094a-83cd-4006-bdd6-251362839ada

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 1, Silent 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA1 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as rs899297502, COSV66926004; called by muse, mutect2, varscan2
- CSMD1 | c.9610G>A p.G3204S (on ENST00000520002; = p.G3203S on NM_033225.6) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1259302833, COSV59403684; called by muse, mutect2, varscan2
- IGSF9B | c.2945C>T p.P982L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs375067578; called by muse, mutect2, varscan2
- SLC12A5 | c.497C>T p.T166M (on ENST00000454036 / NM_001134771.2; = p.T143M on NM_020708.5) | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs764963565; called by mutect2, varscan2
- TGFBI | c.1033A>G p.T345A | Missense Mutation (SNP) | VAF 78/160 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1277140764; called by muse, mutect2, varscan2
- CNTNAP3B | c.2057C>G p.T686R | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GAB4 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKCZ | c.1174C>A p.L392I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); called by muse, mutect2
- SCN1A | c.3149C>G p.P1050R (on ENST00000303395 / NM_001202435.3; = p.P1039R on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- PCDHA12 | c.1419C>T p.H473= | Silent (SNP) | VAF 76/186 reads (41%) | called by mutect2, varscan2
- DDB1 | c.-15G>T | 5'UTR (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- HSPG2 | c.10454-103G>T | Intron (SNP) | VAF 5/46 reads (11%) | catalogued as rs1404841037; called by muse, mutect2
- MUC2 | chr11:1099446 T>A | 5'Flank (SNP) | VAF 16/92 reads (17%) | catalogued as rs56290335; called by muse, varscan2
